Somatic mutation profile of tumor specimen TCGA-B1-7332-01A (aliquot TCGA-B1-7332-01A-11D-2136-08) from TCGA case TCGA-B1-7332, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Age at diagnosis: 61.0 years (22,277 days).
Specimen TCGA-B1-7332-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) ef5e3651-6e1e-4c4d-a7d5-245c2cddb4a5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-B1-7332-10A (Blood Derived Normal), aliquot TCGA-B1-7332-10A-01D-2136-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/db90f045-ffd3-44f0-afbe-bc1fd1bb3ef1

The open-access MAF lists 52 somatic variants for this specimen: 38 protein-altering or splice-affecting, 14 silent.
By variant classification: Missense Mutation 31, Silent 14, Frame Shift Del 5, In Frame Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- MET | c.3598T>A p.F1200I | Missense Mutation (SNP) | VAF 10/28 reads (36%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59259299, COSV59268163; called by muse, mutect2, varscan2
- ADAMTSL3 | c.1627G>T p.V543L | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV99717274; called by muse, mutect2
- APOL5 | c.1120C>T p.P374S | Missense Mutation (SNP) | VAF 14/35 reads (40%) | SIFT tolerated, low confidence (0.32); PolyPhen benign (0.043); catalogued as COSV99968341; called by muse, mutect2, varscan2
- ATP11C | c.2627T>C p.L876P | Missense Mutation (SNP) | VAF 63/143 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100557508; called by muse, mutect2, varscan2
- ATP1B1 | c.494A>T p.E165V | Missense Mutation (SNP) | VAF 23/56 reads (41%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV100891610; called by muse, mutect2, varscan2
- C4orf51 | c.557C>T p.A186V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as COSV101439982; called by muse, mutect2, varscan2
- COL6A3 | c.1607T>C p.L536P | Missense Mutation (SNP) | VAF 28/182 reads (15%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.883); catalogued as COSV99796408; called by muse, mutect2, varscan2
- DDX3X | c.716G>T p.S239I (on ENST00000399959; = p.S240I on NM_001356.5) | Missense Mutation (SNP) | VAF 10/84 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV101302356; called by muse, mutect2, varscan2
- DROSHA | c.3776A>G p.N1259S | Missense Mutation (SNP) | VAF 21/35 reads (60%) | SIFT deleterious (0.03); PolyPhen benign (0.18); catalogued as COSV100757498; called by muse, mutect2, varscan2
- FZD7 | c.968G>A p.G323D | Missense Mutation (SNP) | VAF 23/118 reads (19%) | SIFT tolerated (0.09); PolyPhen benign (0.022); catalogued as COSV53809178; called by muse, mutect2, varscan2
- HEXA | c.1465T>A p.L489M | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT tolerated (0.11); PolyPhen benign (0.011); catalogued as COSV99173682; called by muse, mutect2, varscan2
- IARS2 | c.85T>C p.C29R | Missense Mutation (SNP) | VAF 7/13 reads (54%) | SIFT tolerated, low confidence (0.58); PolyPhen benign (0); catalogued as rs1167991391, COSV100228106; called by muse, mutect2, varscan2
- JAZF1 | c.598A>G p.T200A | Missense Mutation (SNP) | VAF 3/42 reads (7%) | SIFT tolerated (0.14); PolyPhen probably damaging (0.969); catalogued as COSV99386125; called by muse, mutect2
- KANSL1 | c.2947T>C p.S983P (on ENST00000574590 / NM_001193465.2; = p.S984P on NM_015443.4) | Missense Mutation (SNP) | VAF 36/99 reads (36%) | SIFT tolerated (0.22); PolyPhen benign (0); catalogued as COSV99289860; called by muse, mutect2, varscan2
- KATNAL1 | c.650A>G p.K217R | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0); PolyPhen possibly damaging (0.725); catalogued as COSV101016739; called by muse, mutect2, varscan2
- LRP2 | c.8416T>C p.C2806R | Missense Mutation (SNP) | VAF 17/99 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99786790; called by muse, mutect2, varscan2
- METTL9 | c.851G>T p.G284V | Missense Mutation (SNP) | VAF 16/65 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV99193613; called by muse, mutect2, varscan2
- NMNAT2 | c.483C>G p.S161R | Missense Mutation (SNP) | VAF 14/52 reads (27%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.604); catalogued as COSV54266481, COSV99679736; called by muse, mutect2, varscan2
- PLVAP | c.427T>G p.C143G | Missense Mutation (SNP) | VAF 51/132 reads (39%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99391502; called by muse, mutect2, varscan2
- PLXNB2 | c.1111T>A p.Y371N | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT tolerated (0.45); PolyPhen benign (0.298); catalogued as COSV100833875; called by muse, mutect2, varscan2
- POLR3G | c.441A>G p.I147M (on ENST00000399107; = p.T138A on NM_006467.3 and 4 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 10/36 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.055); catalogued as rs998665890, COSV101209764; called by muse, mutect2, varscan2
- PRX | c.964G>A p.V322M | Missense Mutation (SNP) | VAF 9/33 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as COSV99397518; called by muse, mutect2, varscan2
- RD3 | c.113G>T p.R38L | Missense Mutation (SNP) | VAF 27/53 reads (51%) | SIFT deleterious (0); PolyPhen benign (0.331); catalogued as COSV100879193; called by muse, mutect2, varscan2
- ROR1 | c.507C>A p.F169L | Missense Mutation (SNP) | VAF 44/104 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.196); catalogued as COSV100934988; called by muse, mutect2, varscan2
- RRNAD1 | c.1061C>T p.P354L | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.391); catalogued as rs1463402545, COSV100836886; called by muse, mutect2
- SMCHD1 | c.5147C>T p.T1716I | Missense Mutation (SNP) | VAF 16/42 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.143); catalogued as COSV99860792; called by muse, mutect2, varscan2
- SMU1 | c.1401C>G p.Y467* | Nonsense Mutation (SNP) | VAF 13/61 reads (21%) | catalogued as COSV101238503; called by muse, mutect2, varscan2
- STRIP1 | c.821G>T p.C274F | Missense Mutation (SNP) | VAF 45/134 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV100873948; called by muse, mutect2, varscan2
- TMEM201 | c.262G>A p.A88T | Missense Mutation (SNP) | VAF 17/54 reads (31%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs763088816, COSV100440288, COSV61051512; called by muse, mutect2, varscan2
- TRPS1 | c.698G>A p.G233D (on ENST00000220888 / NM_001330599.2; = p.G246D on NM_014112.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 38/111 reads (34%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV55254279, COSV99628794; called by muse, mutect2, varscan2
- UGT1A9 | c.15del p.W6Gfs*13 | Frame Shift Del (DEL) | VAF 17/71 reads (24%) | catalogued as COSV60843307; called by mutect2, pindel, varscan2
- USH2A | c.10928A>G p.H3643R | Missense Mutation (SNP) | VAF 22/51 reads (43%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.958); catalogued as rs772499596, COSV100230015; ClinVar: uncertain significance; called by mutect2, varscan2
- WASF1 | c.1133C>T p.A378V | Missense Mutation (SNP) | VAF 3/48 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.968); catalogued as COSV100846787; called by muse, mutect2
- DHX15 | c.1361del p.E454Gfs*5 | Frame Shift Del (DEL) | VAF 16/58 reads (28%) | called by mutect2, pindel, varscan2
- PCNT | c.8431del p.V2811Cfs*29 | Frame Shift Del (DEL) | VAF 6/39 reads (15%) | called by mutect2, pindel, varscan2
- SLC25A12 | c.722_723del p.G241Dfs*6 | Frame Shift Del (DEL) | VAF 13/127 reads (10%) | called by mutect2, pindel, varscan2
- UTP25 | c.483del p.K161Nfs*23 | Frame Shift Del (DEL) | VAF 28/83 reads (34%) | called by mutect2, pindel, varscan2
- ZDHHC3 | c.404_406del p.I135del | In Frame Del (DEL) | VAF 24/144 reads (17%) | called by mutect2, pindel, varscan2
- ADTRP | c.486C>T p.A162= | Silent (SNP) | VAF 7/40 reads (18%) | catalogued as COSV99995074; called by muse, mutect2, varscan2
- DAG1 | c.855A>G p.A285= | Silent (SNP) | VAF 43/98 reads (44%) | catalogued as COSV100444746; called by muse, mutect2, varscan2
- DLGAP3 | c.1140C>T p.T380= | Silent (SNP) | VAF 40/110 reads (36%) | catalogued as rs149715442, COSV52394832; called by muse, mutect2, varscan2
- DOCK5 | c.3378C>A p.P1126= | Silent (SNP) | VAF 16/40 reads (40%) | catalogued as COSV99376205; called by mutect2, varscan2
- EPPK1 | c.5826C>T p.D1942= | Silent (SNP) | VAF 24/59 reads (41%) | catalogued as rs576788732, COSV101599751; called by muse, mutect2, varscan2
- IGKV1-17 | c.96C>A p.S32= | Silent (SNP) | VAF 4/44 reads (9%) | catalogued as rs748023822; called by muse, varscan2
- KIFBP | c.423G>C p.A141= | Silent (SNP) | VAF 14/23 reads (61%) | catalogued as COSV100741356; called by muse, mutect2, varscan2
- LAMA5 | c.2391C>T p.C797= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV99438335; called by muse, mutect2, varscan2
- MED22 | c.453A>G p.E151= | Silent (SNP) | VAF 6/38 reads (16%) | catalogued as COSV100648031; called by muse, mutect2
- POU4F2 | c.1095C>T p.A365= | Silent (SNP) | VAF 28/87 reads (32%) | catalogued as COSV99850331; called by muse, mutect2, varscan2
- PYGB | c.228C>T p.Y76= | Silent (SNP) | VAF 3/21 reads (14%) | catalogued as rs1272631226, COSV99404891; called by muse, mutect2
- WIZ | c.162G>A p.K54= | Silent (SNP) | VAF 29/73 reads (40%) | catalogued as COSV99652737; called by muse, mutect2, varscan2
- ZBTB40 | c.3435C>A p.T1145= | Silent (SNP) | VAF 7/33 reads (21%) | catalogued as COSV100988830; called by muse, mutect2, varscan2
- ZNF652 | c.1221T>C p.H407= | Silent (SNP) | VAF 31/238 reads (13%) | catalogued as COSV100755553; called by muse, mutect2, varscan2
